CPTAC case C3N-01179 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/000ead0d-abf5-4606-be04-1ea31b999840

Demographics
Sex at birth: male; Race: white; Year of birth: 1944; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 72.5 years (26,483 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,816 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,816 days (5.0 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 380 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 754 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,077 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,476 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 1,476 days (4.0 years); Disease response: Complete Response.
- Days to follow up: 1,816 days (5.0 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 72 kg; Height: 164 cm; BMI: 26.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 70.5; Cigarettes per day: 30; Tobacco smoking onset year: 1962; Tobacco smoking quit year: 2009; Exposure duration years: 47.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01179-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 240 mg; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01179-21: Section location: Middle; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3N-01179-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 205 mg.
- Sample C3N-01179-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 475 mg; Time between excision and freezing: 8 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01179-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
